Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A9OX, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A9OX-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

ICD-6 3
Adenocarcinoma NOS 5140/3
Site: Prostate NOS C61.9
JCO 3/27/14

- A. Anterior prostatic fat, excision: Benign fibroadipose tissue.
- B. Prostate, left lateral margin, biopsy: Benign fibroconnective tissue.
- C. Lymph nodes, right pelvic, dissection: No tumor in four lymph nodes (0/4).
- D. Lymph nodes, left pelvic, dissection: No tumor in four lymph nodes (0/4).
- E. Prostate and seminal vesicles, radical prostatectomy:
- 1. Prostatic adenocarcinoma, Gleason score 3+5=8, margins negative; see comment.
- 2. Seminal vesicles with no tumor.

COMMENT:

The tumor is composed of admixed Gleason patterns 3, 4, and 5, with approximately 50% of the tumor showing Gleason pattern 3, 40% showing Gleason pattern 4, and 10% showing Gleason pattern 5. According to Gleason grading guidelines (see reference below), if >5% of the tumor shows a tertiary Gleason pattern with the highest grade, then this grade should be reflected in the overall score. Thus, in this case, since 10% of the tumor shows Gleason pattern 5, we have assigned Gleason score 3+5=8.

Synoptic Comment for Prostate Tumors

- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:** Left posterior apex, slides E1 and E9; left posterior mid gland, slide E10; left posterior base, slide E11; left anterior apex, slide E12; left anterior mid gland, slide E13; left anterior base, slide E14; right posterior apex, slides E2 and E6; right posterior mid gland, slide E7; right posterior base, slide E8; right anterior apex, slide E3; right anterior mid gland, slide E4; right anterior base, slide E5.
- **Estimated volume of tumor:** 4.7 cm³.
- **Gleason score:** 3+5; primary pattern 3, secondary pattern 4.
-

[page 2 of 3]
-
- **Estimated volume > Gleason pattern 3:** 50%.
- **Involvement of capsule:** Tumor invades capsule at the left posterior mid gland (slide E10).
- **Extraprostatic extension:** None.
- **Margin status for tumor:** Negative.
- **Margin status for benign prostate glands:** No benign glands present at inked excision margins.
- **High-grade prostatic intraepithelial neoplasia (HGPIN):** Present; focally.
- **Tumor involvement of seminal vesicle:** None.
- **Perineural infiltration:** Present.
- **Lymph node status:** Negative; total number of nodes examined: 8.
- **AJCC/UICC stage:** pT2cN0.

Level sections were performed and evaluated on block E6 to confirm the diagnosis.

Reference:

Epstein JI. An Update on the Gleason grading system. Journal of Urology. 2010 Feb;183:433-440.

Specimen(s) Received

A:Anterior prostatic fat tissue
B:Left lateral margin
C:Lymph node, right pelvic
D:Lymph node, left pelvic
E:Prostate and seminal vesicles

Clinical History

The patient is a [REDACTED]-year-old male with prostate cancer ranging in grade from 3+3 to 4+5 ([REDACTED] case [REDACTED]). He now undergoes radical prostatectomy.

Gross Description

The specimen is received in five parts, each labeled with the patient's name and medical record number. Parts A-D are received in formalin. Part E is received fresh.

Part A, additionally labeled "anterior prostatic fat tissue (perm)," consists of multiple fragments of irregular, deep-yellow, lobulated adipose tissue (4.2 x 3 x 0.3 cm in aggregate). No lymph nodes are identified. The specimen is entirely submitted in cassettes A1-A3.

Part B, additionally labeled "left lateral margin (perm)," consists of one unoriented, rectangular fragment of rubbery, dusky-gray, membranous soft tissue (1 x 0.5 x 0.2 cm), entirely submitted in cassette B1.

Part C, additionally labeled "right pelvic lymph nodes - perm," consists of multiple irregular fragments of rubbery, deep-yellow, lobulated adipose tissue (4.2 x 4 x 0.8 cm in aggregate) that contain four rubbery, ovoid, tan to gray, firm lymph nodes (0.5-3.5 cm in greatest dimension). The specimen is entirely submitted as follows:

C1: Three lymph nodes, intact.
C2-C3: Largest lymph node, sectioned.
C4-C5: Remaining soft tissue.

Part D, additionally labeled "left pelvic lymph nodes - perm," consists of multiple fragments of irregular, rubbery, deep-yellow, lobulated adipose tissue (3.5 x 3.5 x 0.8 cm in aggregate) that contain three rubbery, ovoid, tan, firm lymph nodes (0.5-3.4 cm in greatest dimension). The specimen is entirely submitted as follows:

D1: Two lymph nodes, intact.
D2-D3: One lymph node, sectioned.
D4-D5: Remaining soft tissue.

Part E, additionally labeled "prostate + seminal vesicles," consists of a prostate gland (47 gm; 3.5 cm

[page 3 of 3]
from apex to base x 4.5 cm in width x 3.5 cm from anterior to posterior).

GROSS PATHOLOGIC FINDINGS: One ill-defined, pale-tan to yellow, gritty, firm lesion is identified in the posterior aspect of the gland, in both the right and left lobes (2.2 x 1.8 x 1 cm) extending from the apex through to slice 5, multifocally less than 0.1 cm from the capsule. The surrounding parenchyma is pale-tan, spongy with a few well-circumscribed, rubbery periurethral nodules (up to 0.4 cm in greatest dimension). The anterior fibrous tissue is open. The remaining capsule is intact. The seminal vesicles/vas deferens bundles (right 4 x 2 x 0.5 cm; left 3.5 x 2 x 1 cm) are tan-pink and lobulated.

ORIENTED BY: Anatomic landmarks (seminal vesicles, urethra).

INKING:

- Right anterior: Green.

- Left anterior: Blue.

- Posterior: Black.

POTENTIAL STUDIES: Snap frozen.

GROSS PHOTOGRAPHS: Yes.

TOTAL NUMBER OF SLICES: 8; not including apex and base margin slices.

AVERAGE SLICE THICKNESS: 0.4 cm.

CASSETTES: Representative sections are submitted as follows:

Apical margins, entirely submitted in perpendicular sections

E1: Left.

E2: Right.

Right anterior quadrant

E3: Slice 2.

E4: Slice 4.

E5: Slice 6.

Right posterior quadrant

E6: Slice 2.

E7: Slice 4.

E8: Slice 6.

Left posterior quadrant

E9: Slice 2.

E10: Slice 4.

E11: Slice 6.

Left anterior quadrant

E12: Slice 2.

E13: Slice 4.

E14: Slice 6.

Bladder margins, entirely submitted in perpendicular sections

E15-E17: Right.

E18-E20: Left.

Prostatic/seminal vesicle junction and cross-section of vas deferens

E21: Right.

E22: Left.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations, including prosector work, and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

Electronically signed out on

Source: NCI Genomic Data Commons file cb238d7b-1472-41d0-81e2-1c3fc4dc4862 (TCGA-V1-A9OX.4D42611A-3A08-4A1A-A033-13E810FCCA3E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).